Somatic mutation profile of tumor specimen 0DIKK4 from CCDI case PBBVSC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 10.3 years (3,755 days).
Specimen 0DIKK4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a8509fa-7e41-4006-a2b2-e651d499da3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIKJH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbe706b8-f1ab-4710-8f37-ee481b1f1414

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 3, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRIQ3 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 223/1153 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs374700532, COSV63049390; called by muse, mutect2, varscan2
- MYO18B | c.6076C>T p.R2026W | Missense Mutation (SNP) | VAF 69/514 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs753680676; called by muse, mutect2, varscan2
- OR9I1 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 215/1019 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs757448772; called by muse, mutect2, varscan2
- PIP4K2C | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 118/992 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs368437479; called by muse, mutect2, varscan2
- PLEC | c.8695G>A p.E2899K (on ENST00000322810 / NM_201380.4; = p.E2789K on NM_000445.5) | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as rs1554686136, COSV59689964; called by muse, mutect2
- PPP1R3A | c.2833C>A p.P945T | Missense Mutation (SNP) | VAF 32/1090 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52882500; called by muse, mutect2
- RBP3 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as rs782705267; called by muse, mutect2, varscan2
- SHBG | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 96/862 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); catalogued as rs1003392537; called by muse, mutect2, varscan2
- SLITRK6 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 283/649 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV68390003; called by muse, mutect2, varscan2
- TEX15 | c.5674G>A p.A1892T (on ENST00000256246; = p.A2275T on NM_001350162.2) | Missense Mutation (SNP) | VAF 341/1513 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs768024027, COSV99820763; called by muse, mutect2, varscan2
- WEE2 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 190/1200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101285242; called by muse, mutect2, varscan2
- ADAM28 | c.941T>A p.M314K | Missense Mutation (SNP) | VAF 289/791 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PHF3 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 355/970 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- RAD51D | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 686/1164 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, varscan2
- THSD1 | c.1406G>T p.C469F | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- UGT2A1 | c.1098del p.A368Lfs*37 | Frame Shift Del (DEL) | VAF 499/1216 reads (41%) | called by mutect2, varscan2
- C1orf43 | c.741C>T p.N247= (on ENST00000368521 / NM_001297718.2; = p.N213= on NM_015449.4) | Silent (SNP) | VAF 27/936 reads (3%) | called by muse, mutect2
- GRK7 | c.120C>A p.P40= | Silent (SNP) | VAF 20/442 reads (5%) | called by muse, mutect2
- PCDHA10 | c.1968G>A p.P656= | Silent (SNP) | VAF 377/1069 reads (35%) | catalogued as COSV56515075; called by muse, mutect2
- PEX11A | c.300C>T p.D100= | Silent (SNP) | VAF 19/491 reads (4%) | catalogued as rs1273167280; called by muse, mutect2
- RHBDD3 | c.435G>C p.P145= | Silent (SNP) | VAF 93/375 reads (25%) | called by muse, mutect2, varscan2
- TRIM22 | c.867T>A p.V289= | Silent (SNP) | VAF 79/672 reads (12%) | called by muse, mutect2, varscan2
- WDFY2 | c.1197G>T p.V399= | Silent (SNP) | VAF 292/840 reads (35%) | called by mutect2, varscan2
- CD300A | c.667-60C>T | Intron (SNP) | VAF 10/57 reads (18%) | catalogued as rs955023118; called by muse, mutect2, varscan2
- MAGED1 | c.45+343_45+346del | Intron (DEL) | VAF 117/310 reads (38%) | called by mutect2, varscan2
- PHF12 | c.2089+46C>A | Intron (SNP) | VAF 177/596 reads (30%) | called by muse, mutect2, varscan2
- SNAP25 | c.*92T>A | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
